Gene-level copy-number profile of tumor specimen TCGA-AN-A049-01A from TCGA case TCGA-AN-A049, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.2 years (22,710 days).
Specimen TCGA-AN-A049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.4b29c2ad-b966-4f56-b97b-35f5d4aea434.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A049-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2bee79df-9f36-4b73-9330-c1ade5aaa8b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,588; copy number 2: 36,062; copy number 3: 6,817; copy number 4: 3,558; copy number 5: 95; copy number 6: 691.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A049-01A-21D-A011-01): tumor purity 0.69, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 786 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,767,558–198,222,513, 488 genes, copy number 5–6 (broad region; genes not listed).
- chr17:33,013,087–34,174,964, 1 gene, copy number 6 (within-gene range 2–6): ASIC2.
- chr17:33,529,787–40,598,585, 297 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,375. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
